Gene-level copy-number profile of tumor specimen TCGA-GI-A2C8-01A from TCGA case TCGA-GI-A2C8, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 63.3 years (23,103 days).
Specimen TCGA-GI-A2C8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.d986386e-b0cc-46f5-a9dc-8e0c58178f4a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GI-A2C8-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/71eafb07-d88d-47d3-853b-f0b61af04bef

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 38; copy number 1: 428; copy number 2: 20,079; copy number 3: 22,251; copy number 4: 11,053; copy number 5: 1,785; copy number 6: 3,214; copy number 7: 103; copy number 8: 111; copy number 9: 60; copy number 11: 59; copy number 12: 26; copy number 13: 68; copy number 14: 198; copy number 15: 43; copy number 16: 54; copy number 19: 86; copy number 20: 46; copy number 23: 7; copy number 24: 4; copy number 25: 48; copy number 28: 52.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GI-A2C8-01A-11D-A16C-01): tumor purity 0.48, ploidy 3.09, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 38 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:12,115,547–12,395,177, 3 genes: AC005244.1, AC005244.2, AC084167.1.
- chr17:15,565,483–16,218,185, 35 genes: CDRT1, AC005324.2, SNORA74, AC005838.1, TRIM16, AC005324.4, ZNF29P, ZNF286A, AC005324.3, UBE2SP1, TBC1D26, TBC1D26-AS1, AC005324.5, AC005324.1, CDRT15P2, ZSWIM5P1, RNA5SP436, IL6STP1, MEIS3P1, AC015922.2, AC015922.3, AC015922.1, LINC02087, SPECC1P1, ADORA2B, ZSWIM7, TTC19, AC002553.2, NCOR1, AC002553.1, RPLP1P11, RPL22P21, RNU6-314P, RNU6-862P, RN7SL442P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 965 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:199,752,491–201,127,184, 30 genes, copy number 7 (within-gene range 6–7): AL596266.1, AL445687.1, RNU6-778P, AL445687.2, RNU6-716P, RNU6-609P, NR5A2, RNU6-570P, AC096633.1, CCNQP1, LINC00862, AC097065.2, AC097065.1, AC104461.1, ZNF281, AL359834.1, KIF14, DDX59, DDX59-AS1, CAMSAP2, RPL34P6, GPR25, INAVA, MROH3P, RNU6-704P, KIF21B, AL358473.1, AL358473.2, CACNA1S, ASCL5.
- chr3:84,940,619–84,947,061, 1 gene, copy number 7: AC132660.2.
- chr8:60,046,755–72,470,972, 182 genes, copy number 8–23 (broad region; genes not listed).
- chr8:79,611,117–80,613,826, 32 genes, copy number 20: STMN2, AC016240.1, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P.
- chr8:80,644,939–80,645,173, 1 gene, copy number 20: CKS1BP7.
- chr8:89,757,806–95,156,685, 106 genes, copy number 14–20 (broad region; genes not listed).
- chr8:98,371,228–107,195,938, 176 genes, copy number 7–14 (broad region; genes not listed).
- chr11:32,112,049–32,343,409, 1 gene, copy number 25 (within-gene range 5–25): THEM7P.
- chr11:32,387,775–38,212,799, 99 genes, copy number 25–28 (broad region; genes not listed).
- chr11:40,114,203–41,459,773, 1 gene, copy number 24 (within-gene range 2–24): LRRC4C.
- chr11:41,122,907–41,426,504, 2 genes, copy number 24: RNU6-365P, AC090138.1.
- chr11:41,538,434–41,538,986, 1 gene, copy number 24: AC021006.1.
- chr11:43,578,889–43,840,030, 1 gene, copy number 19 (within-gene range 2–19): AC068205.2.
- chr11:43,680,680–43,920,944, 10 genes, copy number 19: HSD17B12, AC068205.3, RPL23AP63, PHBP2, AC068205.4, AC087521.2, AC087521.4, ALKBH3, SEC14L1P1, ALKBH3-AS1.
- chr11:43,925,342–43,943,878, 1 gene, copy number 19 (within-gene range 5–19): C11orf96.
- chr11:44,047,981–44,310,139, 5 genes, copy number 23: ACCSL, ACCS, AC134775.1, EXT2, ALX4.
- chr12:38,532,895–38,589,812, 2 genes, copy number 20: AC087897.1, AC087897.2.
- chr12:57,546,026–60,419,293, 63 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr12:64,442,510–65,966,291, 40 genes, copy number 8–16 (within-gene range 2–16): AC135279.2, AC135279.3, TBK1, AC136977.1, RASSF3, AC078962.2, SNORD83, AC078962.4, MIR548C, MIR548Z, AC078962.1, AC078962.3, AC025262.2, AC025262.1, GNS, TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1.
- chr17:32,007,872–32,491,253, 33 genes, copy number 9–16 (within-gene range 2–16): LRRC37B, AC090616.4, SH3GL1P1, AC090616.6, AC090616.2, AC090616.5, AC090616.1, WDR45BP1, AC116407.2, AC116407.1, RHOT1, ARGFXP2, AC116407.4, AC116407.3, UBL5P2, AC026620.2, RHBDL3, AC026620.1, AC005899.4, C17orf75, AC005899.3, OOSP1P2, MIR632, ZNF207, AC005899.6, AC005899.7, AC005899.5, AC005899.8, AC005899.1, AC005899.2, PSMD11, Y_RNA, CDK5R1.
- chr17:32,495,536–32,531,492, 7 genes, copy number 16: AC079336.5, AC079336.7, AC079336.2, AC079336.1, AC079336.6, AC079336.4, AC079336.3.
- chr17:32,876,759–32,997,877, 4 genes, copy number 9: AC084809.1, AC084809.2, TMEM98, SPACA3.
- chr17:54,477,796–54,703,430, 3 genes, copy number 9: ISCA1P3, AC015943.1, AC005951.1.
- chr17:59,400,488–64,146,476, 164 genes, copy number 8–19 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 211. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
